Somatic mutation profile of tumor specimen TCGA-AA-3984-01A (aliquot TCGA-AA-3984-01A-02W-0995-10) from TCGA case TCGA-AA-3984, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.8 years (22,585 days).
Specimen TCGA-AA-3984-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1665f2bf-4ddc-47ba-9ef3-a94c71db82bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3984-10A (Blood Derived Normal), aliquot TCGA-AA-3984-10A-01D-1982-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b29d802-6849-4565-b39c-88c0622525d4

The open-access MAF lists 4,931 somatic variants for this specimen: 3,887 protein-altering or splice-affecting, 943 silent, 101 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,365, Silent 943, Nonsense Mutation 432, Intron 49, Splice Site 45, RNA 27, Splice Region 26, Frame Shift Ins 14, 3'UTR 13, 3'Flank 6, 5'Flank 3, Nonstop Mutation 3.

Variants (750 of 4,931; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61750065, CM990038, COSV64672644; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7A | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | catalogued as rs797045337, COSV100430703; ClinVar: pathogenic; called by muse, mutect2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 50/192 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- BRCA1 | c.4508C>A p.S1503* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs80357437, CM062470, COSV100524045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CA8 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs387906598, CM118190, COSV58771796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 62/222 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, varscan2
- CFTR | c.2551C>T p.R851* | Nonsense Mutation (SNP) | VAF 59/280 reads (21%) | catalogued as rs121909012, CM910073, COSV99135243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*2480C>T | 3'UTR (SNP) | VAF 7/58 reads (12%) | catalogued as rs375009168, CM141804, COSV99950416; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FBN1 | c.8521G>T p.E2841* | Nonsense Mutation (SNP) | VAF 36/552 reads (7%) | catalogued as rs587782948, CM118006, COSV57310584, COSV57313168; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 62/214 reads (29%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1558G>T p.D520Y (on ENST00000281708 / NM_001349798.2; = p.D440Y on NM_018315.5) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895090, COSV55923112, COSV55961967; called by muse, mutect2, varscan2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 51/312 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- FOXP3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs28935477, CM010059, COSV66050988; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72555358, CM910181, COSV56566787; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 55/359 reads (15%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.2672dup p.N891Kfs*2 | Frame Shift Ins (INS) | VAF 60/226 reads (27%) | catalogued as rs763860580; ClinVar: pathogenic; called by mutect2, varscan2
- NMNAT1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs375110174, CM127766; ClinVar: pathogenic; called by mutect2, varscan2
- OCRL | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 102/666 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853260, CM981410, COSV63980092; ClinVar: pathogenic; called by muse, varscan2
- OTX2 | c.202C>T p.R68* (on ENST00000408990 / NM_172337.3; = p.R76* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as rs773157352, COSV59766871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- PTH | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs199955107, CM1511342, COSV56378577; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RARS2 | c.419T>G p.F140C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772887102, CM162129, COSV101057238; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC37A4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193302903, CM980800, COSV100421525; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as rs753621591, CM121226, COSV56252267; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, varscan2
- A1CF | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as rs772118222, COSV50957228; called by muse, mutect2, varscan2
- A1CF | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs754321707, COSV99256036; called by muse, mutect2, varscan2
- A2M | c.2098C>G p.P700A | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100588637; called by muse, mutect2, varscan2
- A2M | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV59393078; called by muse, mutect2, varscan2
- A2ML1 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100228872; called by muse, varscan2
- A2ML1 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770246364, COSV55288421; called by muse, varscan2
- A2ML1 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100228874; called by muse, varscan2
- A2ML1 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as rs370203983; called by muse, varscan2
- A2ML1 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.177); catalogued as COSV100228879; called by muse, varscan2
- AACS | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 83/588 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.816); catalogued as COSV99907978; called by muse, mutect2, varscan2
- AADACL3 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100206691; called by muse, mutect2, varscan2
- AARD | c.35G>T p.R12I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs1392831257, COSV100991889; called by muse, mutect2
- AARS2 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771412; called by muse, mutect2, varscan2
- AARS2 | c.1897A>G p.T633A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99771418; called by muse, mutect2, varscan2
- ABAT | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99190936; called by muse, mutect2, varscan2
- ABCA1 | c.6575G>A p.S2192N | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101036867, COSV66065047; called by muse, mutect2, varscan2
- ABCA1 | c.4866G>T p.E1622D | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV101036869; called by muse, mutect2, varscan2
- ABCA1 | c.1127A>G p.K376R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV101036870; called by muse, varscan2
- ABCA10 | c.2460G>T p.K820N | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99288550, COSV99289532; called by muse, mutect2, varscan2
- ABCA10 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99288558; called by muse, mutect2, varscan2
- ABCA12 | c.2682C>A p.L894= (on ENST00000272895 / NM_173076.3; = p.L576= on NM_015657.3) | Splice Region (SNP) | VAF 22/220 reads (10%) | catalogued as COSV99789742; called by muse, mutect2
- ABCA12 | c.1522A>G p.K508E (on ENST00000272895 / NM_173076.3; = p.K190E on NM_015657.3) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV99789743; called by muse, mutect2, varscan2
- ABCA13 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV101330026; called by muse, mutect2, varscan2
- ABCA13 | c.7949A>G p.E2650G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101446929; called by muse, mutect2, varscan2
- ABCA13 | c.8596G>T p.E2866* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs551407561, COSV101446931; called by muse, mutect2, varscan2
- ABCA13 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 74/1237 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1163099421, COSV68948669; called by muse, mutect2
- ABCA13 | c.14590A>C p.K4864Q | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291321; called by muse, mutect2, varscan2
- ABCA4 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV64679321; called by muse, mutect2, varscan2
- ABCA6 | c.3674G>T p.R1225I | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52646867; called by muse, varscan2
- ABCA6 | c.3475A>G p.M1159V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV52646466; called by muse, mutect2, varscan2
- ABCA6 | c.2781A>C p.Q927H | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52644825, COSV99446380; called by muse, mutect2, varscan2
- ABCA6 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52637755; called by muse, mutect2, varscan2
- ABCA6 | c.10A>C p.K4Q | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99446384; called by muse, mutect2, varscan2
- ABCA8 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756218261, COSV52200060; called by muse, mutect2
- ABCA9 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV100383068; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB7 | c.2160G>T p.W720C (on ENST00000373394 / NM_001271696.3; = p.W721C on NM_004299.6) | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV99504311; called by muse, mutect2
- ABCB7 | c.1981A>C p.I661L (on ENST00000373394 / NM_001271696.3; = p.I662L on NM_004299.6) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99504316; called by muse, mutect2, varscan2
- ABCC1 | c.2879T>G p.L960R | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100579449; called by muse, mutect2, varscan2
- ABCC10 | c.1634G>A p.R545Q (on ENST00000372530 / NM_001198934.2; = p.R502Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs368489601; called by muse, mutect2, varscan2
- ABCC10 | c.2212C>T p.R738C (on ENST00000372530 / NM_001198934.2; = p.R710C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016532813, COSV99767187; called by muse, varscan2
- ABCC10 | c.4258C>T p.L1420F (on ENST00000372530 / NM_001198934.2; = p.L1392F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99767189; called by muse, mutect2, varscan2
- ABCC2 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 42/153 reads (27%) | catalogued as rs775410341, COSV64984500; called by muse, mutect2, varscan2
- ABCC2 | c.2969C>A p.S990Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV100966490; called by muse, mutect2, varscan2
- ABCC4 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs763493372, COSV65313204; called by muse, mutect2, varscan2
- ABCC5 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs778058381, COSV99656829; called by muse, mutect2, varscan2
- ABCC9 | c.4288A>G p.M1430V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99685542; called by muse, mutect2, varscan2
- ABCD2 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.15); catalogued as COSV100429396; called by muse, mutect2, varscan2
- ABCD2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100429691; called by muse, mutect2
- ABCG1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs1294780786, COSV100494135; called by muse, mutect2, varscan2
- ABCG5 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs368800131; ClinVar: uncertain significance; called by mutect2, varscan2
- ABI3BP | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs199686325, COSV99426521; called by muse, mutect2, varscan2
- ABI3BP | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as rs374566927; called by muse, mutect2, varscan2
- ABI3BP | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV99426525; called by muse, mutect2, varscan2
- ABI3BP | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005975720, COSV52551207; called by muse, mutect2, varscan2
- ABLIM2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315520248, COSV56408122; called by muse, mutect2, varscan2
- ABLIM2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | catalogued as COSV56404755; called by muse, mutect2
- ABLIM3 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100448327; called by muse, mutect2, varscan2
- ABRACL | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs772960368, COSV100866334; called by muse, mutect2
- ACACA | c.4664G>A p.R1555H | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764599804; called by muse, mutect2, varscan2
- ACACB | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100622797; called by muse, mutect2, varscan2
- ACADM | c.143T>G p.F48C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63720642; called by muse, mutect2, varscan2
- ACADSB | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100715175; called by muse, mutect2, varscan2
- ACAN | c.6166C>T p.Q2056* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100717953; called by muse, mutect2, varscan2
- ACE2 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs747988885, COSV99382756; called by muse, mutect2, varscan2
- ACKR3 | c.765C>A p.F255L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56020879, COSV99799526; called by muse, mutect2, varscan2
- ACO1 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.201); catalogued as rs376599072; called by mutect2, varscan2
- ACOX1 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99503533; called by muse, mutect2, varscan2
- ACOX3 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV100711945; called by muse, mutect2, varscan2
- ACP3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs777654881, COSV60484679; called by muse, mutect2, varscan2
- ACRBP | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs779982883, COSV99976093; called by muse, mutect2, varscan2
- ACSBG2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); catalogued as rs758992299, COSV53124024; called by mutect2, varscan2
- ACSL3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62480859; called by muse, mutect2, varscan2
- ACSL4 | c.2107G>T p.D703Y (on ENST00000340800 / NM_022977.2; = p.D662Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/387 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV61615594; called by muse, mutect2
- ACSL4 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 39/181 reads (22%) | catalogued as COSV100538514; called by muse, mutect2, varscan2
- ACSS2 | c.1479C>A p.F493L | Missense Mutation (SNP) | VAF 348/2233 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99489803; called by muse, mutect2, varscan2
- ACSS3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV99698735; called by muse, mutect2
- ACTBL2 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101379313; called by muse, mutect2, varscan2
- ACTL8 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV64861479, COSV64862066; called by muse, mutect2, varscan2
- ACTR1A | c.842T>G p.F281C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV100883718; called by muse, mutect2, varscan2
- ACTR3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs760969306, COSV54302191; called by muse, mutect2
- ACTR5 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs768522307, COSV54759775; called by muse, mutect2, varscan2
- ACVR2A | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as COSV99604458; called by muse, mutect2, varscan2
- ACVR2A | c.1126A>C p.N376H | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV99604461; called by muse, mutect2, varscan2
- ADA2 | c.1203G>T p.K401N (on ENST00000262607; = p.K160N on NM_177405.3) | Missense Mutation (SNP) | VAF 135/648 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV99375995; called by muse, mutect2, varscan2
- ADAM17 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs756129840, COSV100176225; called by muse, mutect2
- ADAM19 | c.1067A>C p.D356A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977012; called by muse, mutect2, varscan2
- ADAM2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV99697267; called by muse, mutect2
- ADAM28 | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99738553; called by muse, mutect2, varscan2
- ADAM29 | c.2016G>T p.K672N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV100821995; called by muse, mutect2, varscan2
- ADAM7 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51538749; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.691); catalogued as rs1323137106, COSV99836038; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV99836039; called by muse, mutect2, varscan2
- ADAMTS1 | c.2509A>G p.K837E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV99536073; called by muse, varscan2
- ADAMTS1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53168803; called by muse, varscan2
- ADAMTS12 | c.2283G>A p.W761* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | catalogued as COSV100710810; called by muse, varscan2
- ADAMTS16 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754871314, COSV56977587; called by muse, mutect2
- ADAMTS17 | c.2467A>G p.T823A | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.277); catalogued as COSV99170599; called by muse, mutect2
- ADAMTS2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771509811, COSV51075719; called by muse, mutect2, varscan2
- ADAMTS20 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 33/171 reads (19%) | catalogued as COSV67134539; called by muse, mutect2, varscan2
- ADAMTS8 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs749975173, COSV99960877; called by muse, mutect2, varscan2
- ADAMTS8 | c.1953A>C p.E651D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99960879; called by muse, mutect2, varscan2
- ADAMTSL1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 242/985 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs200648653, COSV99442517; called by muse, varscan2
- ADAMTSL3 | c.4477T>G p.S1493A | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99718600; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs149442347; called by muse, mutect2, varscan2
- ADAP2 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100437237; called by muse, mutect2, varscan2
- ADCY10 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746591110, COSV63241530; called by muse, mutect2, varscan2
- ADCY4 | c.3188A>G p.N1063S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV60252904; called by muse, varscan2
- ADCY5 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs775356872, COSV100567636, COSV59201837; called by mutect2, varscan2
- ADD1 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 181/856 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV99296391; called by muse, mutect2, varscan2
- ADD2 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV52473422; called by muse, mutect2, varscan2
- ADD2 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 22/669 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); catalogued as COSV52454691; called by muse, mutect2
- ADGRA3 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs928853508, COSV51561936; called by muse, mutect2, varscan2
- ADGRB3 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV65384210; called by muse, mutect2, varscan2
- ADGRB3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs754848273, COSV65395147, COSV65421513; called by muse, varscan2
- ADGRB3 | c.3259T>G p.L1087V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); catalogued as COSV99484899; called by muse, mutect2, varscan2
- ADGRD1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1190105071, COSV55458534; called by muse, mutect2, varscan2
- ADGRD1 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs756810149, COSV55442677; called by muse, mutect2, varscan2
- ADGRE2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs754889485, COSV59693104; called by muse, mutect2, varscan2
- ADGRF5 | c.1833T>G p.A611= | Splice Region (SNP) | VAF 28/124 reads (23%) | catalogued as COSV99345508; called by muse, mutect2, varscan2
- ADGRG4 | c.3760T>G p.L1254V | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99795334; called by muse, varscan2
- ADGRG4 | c.3769G>A p.D1257N | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.569); catalogued as rs762948773, COSV99795335; called by muse, varscan2
- ADGRG6 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1271357229, COSV51598215, COSV99746936; called by muse, mutect2, varscan2
- ADGRG7 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99840959; called by muse, mutect2, varscan2
- ADGRL2 | c.3095A>G p.N1032S (on ENST00000370717 / NM_001366005.1; = p.N1019S on NM_012302.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as COSV99588792; called by muse, mutect2
- ADGRL2 | c.3379C>T p.R1127C (on ENST00000370717 / NM_001366005.1; = p.R1114C on NM_012302.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775087345, COSV54673990, COSV54685771; called by muse, varscan2
- ADGRL3 | c.696G>T p.Q232H (on ENST00000506720 / NM_001322402.2; = p.Q164H on NM_015236.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101547082; called by muse, mutect2, varscan2
- ADGRL4 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1174154617; called by muse, mutect2
- ADGRV1 | c.6590T>G p.L2197R | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101315823, COSV67980076; called by muse, mutect2, varscan2
- ADGRV1 | c.7292C>T p.A2431V | Missense Mutation (SNP) | VAF 88/493 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101315824; called by muse, mutect2, varscan2
- ADGRV1 | c.10300T>G p.L3434V | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); catalogued as COSV101315825; called by muse, mutect2, varscan2
- ADGRV1 | c.15325T>C p.W5109R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101315826; called by muse, mutect2, varscan2
- ADGRV1 | c.16693A>G p.T5565A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV101315827; called by muse, mutect2, varscan2
- ADH1A | c.345C>T p.N115= | Splice Region (SNP) | VAF 14/146 reads (10%) | catalogued as rs1412779396, COSV52926005; called by muse, mutect2
- ADH1C | c.225A>C p.E75D | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV101565179, COSV101565202, COSV72463662; called by muse, mutect2, varscan2
- ADH6 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52954963, COSV99422264; called by muse, mutect2, varscan2
- ADNP | c.1889T>C p.I630T | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.506); catalogued as COSV100823726; called by muse, mutect2, varscan2
- ADNP | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | catalogued as COSV100823727; called by muse, mutect2, varscan2
- AEBP1 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99788745; called by muse, mutect2, varscan2
- AFF4 | c.2281T>G p.S761A | Missense Mutation (SNP) | VAF 80/385 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.176); catalogued as COSV99534881; called by muse, mutect2, varscan2
- AFG1L | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs778941841, COSV100933937; called by muse, mutect2, varscan2
- AFG1L | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV100933938; called by muse, mutect2, varscan2
- AFG3L2 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as rs754307169, COSV99301835; called by muse, mutect2, varscan2
- AFMID | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs926323806, COSV59975724; called by muse, mutect2
- AFTPH | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99480635; called by muse, mutect2, varscan2
- AFTPH | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.347); catalogued as COSV99480641; called by muse, mutect2, varscan2
- AGAP3 | c.2036G>A p.R679H (on ENST00000622464; = p.R715H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750679955, COSV68244885; called by muse, mutect2, varscan2
- AGBL2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs750247007, COSV54094493; called by muse, mutect2, varscan2
- AGL | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 57/188 reads (30%) | catalogued as COSV54049072, COSV54059254, COSV99648854; called by muse, mutect2, varscan2
- AGO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 76/367 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs748561732, COSV64594648; called by muse, mutect2, varscan2
- AGO4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV64617106; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AGTR2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs782176432, COSV64156534, COSV64157083; called by muse, mutect2
- AGXT2 | c.1532G>T p.R511I | Missense Mutation (SNP) | VAF 117/545 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99183744; called by muse, mutect2, varscan2
- AGXT2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs756036796, COSV51487388; called by muse, varscan2
- AGXT2 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV51490389; called by muse, varscan2
- AHCYL1 | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV63208905; called by muse, mutect2
- AHI1 | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99662612; called by muse, mutect2
- AHNAK2 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1188646569, COSV60912557; called by muse, mutect2, varscan2
- AICDA | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV57564989; called by muse, mutect2, varscan2
- AKAP11 | c.4399A>C p.K1467Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99213854; called by muse, mutect2, varscan2
- AKAP13 | c.1782A>C p.K594N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100773688; called by muse, mutect2, varscan2
- AKAP6 | c.5030C>T p.A1677V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99800473; called by muse, mutect2, varscan2
- AKAP6 | c.5684A>G p.E1895G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99800479; called by muse, mutect2, varscan2
- AKAP9 | c.10000C>T p.R3334W (on ENST00000359028; = p.R3310W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs779243745, COSV62337823; called by muse, mutect2, varscan2
- AKIRIN2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57636871; called by muse, mutect2
- AKNA | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as rs746973445, COSV99800235; called by muse, mutect2, varscan2
- AKR1B1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs770279911, COSV53648323; called by muse, mutect2, varscan2
- AKR1C4 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs529198618, COSV54125324; called by muse, mutect2, varscan2
- AKT2 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100251588; called by muse, mutect2, varscan2
- AKT2 | c.1021T>C p.Y341H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100251589; called by muse, varscan2
- AL035461.3 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs771270190, COSV66652084; called by muse, varscan2
- AL035461.3 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 54/352 reads (15%) | catalogued as rs145778654; called by muse, varscan2
- AL121899.2 | c.1706A>C p.E569A | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101198438; called by muse, mutect2, varscan2
- AL121899.2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 41/630 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1205086132, COSV67352495; called by muse, mutect2
- ALAD | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs973089315, COSV99474730; called by muse, mutect2
- ALAS2 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.099); catalogued as COSV100238231; called by muse, mutect2
- ALAS2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100238233; called by muse, mutect2, varscan2
- ALB | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV99891382; called by muse, mutect2, varscan2
- ALDH1A3 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs371736673; called by muse, mutect2, varscan2
- ALDH1L1 | c.721-1G>T p.X241_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99856761; called by muse, mutect2, varscan2
- ALDH3A2 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99449849; called by muse, mutect2, varscan2
- ALDH3B1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780821654, COSV99141861; called by muse, mutect2, varscan2
- ALDH8A1 | c.51A>C p.K17N | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99664681; called by muse, mutect2
- ALG11 | c.1294G>C p.G432R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV101584275; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV52634896; called by mutect2, varscan2
- ALG5 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs544999445, COSV53507460; called by muse, mutect2, varscan2
- ALG8 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55203092; called by muse, mutect2, varscan2
- ALKBH8 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 23/176 reads (13%) | catalogued as COSV99508427, COSV99508661; called by muse, mutect2, varscan2
- ALLC | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 47/393 reads (12%) | catalogued as rs371999138, COSV52997740; called by muse, mutect2, varscan2
- ALMS1 | c.387A>C p.Q129H | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs746391155, COSV52506333; called by muse, mutect2, varscan2
- ALMS1 | c.11885T>G p.F3962C | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042268; called by muse, mutect2, varscan2
- ALOX5 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1047630934, COSV65550945; called by muse, mutect2, varscan2
- ALOXE3 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 16/265 reads (6%) | catalogued as COSV59074205; called by muse, mutect2
- ALPK2 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100864326; called by muse, mutect2, varscan2
- ALPK3 | c.4694A>C p.N1565T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99360788; called by muse, mutect2, varscan2
- ALS2 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1309144602, COSV51887988; called by muse, mutect2, varscan2
- ALS2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs762706628, COSV99969233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBN | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 84/381 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59827212; called by muse, mutect2, varscan2
- AMBRA1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV54049679; called by muse, mutect2, varscan2
- AMDHD1 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 25/152 reads (16%) | catalogued as COSV99900295; called by muse, mutect2, varscan2
- AMDHD1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338270376, COSV99900297; called by muse, mutect2, varscan2
- AMER1 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100365980; called by muse, mutect2, varscan2
- AMER2 | c.1821G>T p.K607N | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100766234; called by muse, mutect2, varscan2
- AMER3 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs756210400, COSV100366172, COSV58465910; called by muse, mutect2, varscan2
- AMMECR1 | c.548A>C p.N183T | Missense Mutation (SNP) | VAF 33/548 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV99466657; called by muse, mutect2
- AMPD1 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142643298; called by muse, mutect2, varscan2
- AMPD1 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100815014; called by muse, mutect2
- ANG | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs141398857, CM1110462, COSV100390908; called by muse, mutect2, varscan2
- ANGPT4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs376414024, COSV67921220; called by muse, mutect2
- ANGPTL5 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57531879, COSV57534940; called by muse, mutect2, varscan2
- ANGPTL5 | c.275G>T p.R92I | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.684); catalogued as COSV100527768, COSV57533138; called by muse, mutect2, varscan2
- ANK3 | c.8352T>G p.F2784L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99779694; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by mutect2, varscan2
- ANKAR | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 16/152 reads (11%) | catalogued as COSV99854172, COSV99854192; called by muse, mutect2
- ANKAR | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV99854175; called by muse, mutect2
- ANKEF1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs145101692; called by muse, mutect2, varscan2
- ANKFN1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV100593419; called by muse, mutect2, varscan2
- ANKH | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99414939, COSV99415545; called by muse, mutect2, varscan2
- ANKH | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1440219037, COSV99414941; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5365C>A p.H1789N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.037); catalogued as COSV51859567, COSV99783151; called by muse, mutect2, varscan2
- ANKIB1 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.366); catalogued as COSV99728962; called by muse, varscan2
- ANKK1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.262); catalogued as rs762261977, COSV58274315; called by muse, mutect2, varscan2
- ANKRA2 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99707010; called by muse, mutect2, varscan2
- ANKRD11 | c.2518C>T p.R840W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761259443, CD162073, COSV56363768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs371617857, COSV100041204; called by muse, mutect2, varscan2
- ANKRD13C | c.1497T>C p.D499= | Splice Region (SNP) | VAF 46/145 reads (32%) | catalogued as COSV99256764; called by muse, mutect2, varscan2
- ANKRD28 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV101080605; called by muse, mutect2, varscan2
- ANKRD33 | c.355C>T p.R119W (on ENST00000340970 / NM_001304459.2; = p.R244W on NM_182608.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764706850, COSV56605673; called by muse, varscan2
- ANKRD35 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100841714; called by muse, mutect2, varscan2
- ANKRD44 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs780836038, COSV99984889; called by muse, mutect2, varscan2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2, varscan2
- ANKRD44 | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV56553501, COSV99984894; called by muse, mutect2
- ANKRD46 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 54/144 reads (38%) | catalogued as rs1480467503, COSV100170018; called by muse, mutect2, varscan2
- ANKRD6 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1485147328, COSV100329815; called by muse, mutect2, varscan2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 211/590 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2, varscan2
- ANKS1B | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245245; called by muse, mutect2, varscan2
- ANLN | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774828191, COSV99732220; called by muse, mutect2, varscan2
- ANLN | c.1696A>C p.N566H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99732222; called by muse, mutect2
- ANLN | c.3356A>C p.K1119T | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV99732223; called by muse, mutect2, varscan2
- ANO2 | c.1955A>G p.Y652C (on ENST00000356134 / NM_001278597.3; = p.Y656C on NM_001278596.3) | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310218589, COSV100500745; called by muse, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- ANO3 | c.2446C>A p.L816I | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99882507; called by muse, mutect2, varscan2
- ANO4 | c.338G>A p.R113Q (on ENST00000392977 / NM_001286615.2; = p.R78Q on NM_178826.4) | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1442015501, COSV100152777, COSV54606721; called by muse, mutect2, varscan2
- ANO6 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs747156509, COSV100263073; called by muse, mutect2, varscan2
- ANO6 | c.2632C>A p.L878I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as COSV100263087; called by muse, mutect2, varscan2
- ANOS1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 124/582 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761052947, COSV99390839; called by muse, mutect2, varscan2
- ANP32E | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs143260001; called by muse, mutect2
- ANXA11 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV99627080; called by muse, mutect2, varscan2
- ANXA13 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99146096; called by muse, mutect2, varscan2
- AOAH | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV51738460; called by muse, mutect2, varscan2
- AOC1 | c.1960C>A p.L654I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV62867598; called by muse, mutect2
- AP002748.5 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV59148777; called by muse, mutect2
- AP1G1 | c.539A>C p.K180T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100250385; called by muse, mutect2, varscan2
- AP3B2 | c.3160A>G p.T1054A (on ENST00000261722; = p.T1048A on NM_004644.5) | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99916445; called by muse, mutect2, varscan2
- AP3M2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 25/339 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99441532; called by muse, mutect2
- APBA1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595980, COSV99597291; called by muse, varscan2
- APBB3 | c.538A>C p.S180R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV100021286; called by muse, mutect2, varscan2
- APC | c.8351T>G p.F2784C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99967584; called by muse, mutect2, varscan2
- APLP2 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as rs773309208, COSV99599671; called by muse, mutect2, varscan2
- APOB | c.11687C>T p.A3896V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as rs759708973, COSV51931713; called by muse, mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- APOB | c.4410T>G p.H1470Q | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99265399; called by muse, mutect2, varscan2
- APOBEC2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs748645869, COSV55142717; called by muse, mutect2, varscan2
- APOBEC3G | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs531397529, COSV101349069; called by muse, varscan2
- AQR | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs980589387, COSV50054153; called by muse, mutect2, varscan2
- ARAP2 | c.1882A>C p.T628P | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100394571; called by muse, mutect2, varscan2
- ARAP2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs551766032, COSV58290634; called by muse, mutect2, varscan2
- ARFGEF1 | c.4894G>A p.D1632N | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs773060622, COSV51602227; called by muse, mutect2, varscan2
- ARFGEF1 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99142173; called by muse, mutect2, varscan2
- ARFGEF2 | c.4760A>G p.D1587G | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV100904234; called by muse, mutect2, varscan2
- ARFIP2 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 37/149 reads (25%) | catalogued as COSV99601502; called by muse, mutect2, varscan2
- ARHGAP10 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776974905, COSV100331201, COSV60599477; called by muse, mutect2, varscan2
- ARHGAP11A | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as rs776172390, COSV64380835; called by muse, mutect2, varscan2
- ARHGAP18 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100936140; called by muse, mutect2
- ARHGAP28 | c.614T>G p.V205G (on ENST00000383472 / NM_001366230.1; = p.V46G on NM_001010000.3) | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as COSV99150208; called by muse, mutect2
- ARHGAP33 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs1314581741, COSV99138114; called by muse, varscan2
- ARHGAP35 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs564899532, COSV68333501; called by muse, mutect2, varscan2
- ARHGAP4 | c.1534T>G p.F512V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100604020; called by muse, varscan2
- ARHGEF11 | c.2554C>T p.R852* | Nonsense Mutation (SNP) | VAF 92/194 reads (47%) | catalogued as COSV100168539; called by muse, mutect2, varscan2
- ARHGEF2 | c.548G>A p.R183Q (on ENST00000361247 / NM_001162383.2; = p.R156Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV100560521; called by muse, mutect2, varscan2
- ARHGEF26 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100726538; called by muse, mutect2, varscan2
- ARHGEF28 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777295435, COSV99708944; called by muse, mutect2, varscan2
- ARHGEF6 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 62/470 reads (13%) | catalogued as COSV99166443; called by muse, mutect2, varscan2
- ARHGEF6 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV51689074; called by muse, mutect2, varscan2
- ARHGEF6 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 199/392 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166445; called by muse, mutect2, varscan2
- ARHGEF9 | c.1111T>G p.Y371D | Missense Mutation (SNP) | VAF 149/380 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as COSV99491712; called by muse, mutect2, varscan2
- ARID1A | c.2999C>A p.S1000Y | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61376095, COSV61380392, COSV61383336; called by muse, mutect2, varscan2
- ARID1B | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs774777278, COSV99268860; called by muse, mutect2, varscan2
- ARID1B | c.5819G>A p.R1940H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684987; called by muse, mutect2, varscan2
- ARID4B | c.3263C>T p.S1088L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs768130451, COSV99935545; called by muse, mutect2, varscan2
- ARL5A | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99706604; called by muse, varscan2
- ARMC12 | c.493G>A p.E165K (on ENST00000373866 / NM_001286574.2; = p.E192K on NM_145028.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV99849453; called by muse, mutect2, varscan2
- ARMC8 | c.65G>A p.R22H (on ENST00000469044 / NM_001363941.2; = p.R8H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61767707; called by muse, mutect2, varscan2
- ARMC8 | c.549T>G p.I183M (on ENST00000469044 / NM_001363941.2; = p.I169M on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV100627626; called by muse, mutect2, varscan2
- ARMCX1 | c.1115A>C p.E372A | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV100863187; called by muse, mutect2, varscan2
- ARMCX2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV57529321, COSV57529549; called by muse, mutect2, varscan2
- ARMH3 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64238719; called by muse, mutect2, varscan2
- ARMT1 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100939784; called by muse, mutect2, varscan2
- ARNT2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57591420; called by muse, mutect2, varscan2
- ARNTL | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100724710, COSV62985616; called by muse, mutect2, varscan2
- ARNTL2 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV99667719; called by muse, varscan2
- ARPP21 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV99491862; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, mutect2, varscan2
- ARR3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 433/1199 reads (36%) | catalogued as rs1192044232, COSV57204706; called by muse, mutect2, varscan2
- ARR3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV99333645; called by muse, mutect2
- ARRDC3 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99475229, COSV99475257; called by muse, mutect2, varscan2
- ARSB | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as COSV53727318, COSV99364688; called by muse, mutect2, varscan2
- AS3MT | c.383A>C p.N128T | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100185690; called by muse, varscan2
- AS3MT | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756960577, COSV100185691; called by muse, varscan2
- ASAP2 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.665); catalogued as rs1139804, COSV99856134; called by muse, mutect2, varscan2
- ASB15 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1173908012, COSV99306481; called by muse, varscan2
- ASB15 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306486; called by muse, mutect2, varscan2
- ASB9 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV100995476; called by muse, mutect2, varscan2
- ASCC3 | c.4409T>C p.V1470A | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64978623; called by muse, mutect2, varscan2
- ASCC3 | c.3590G>A p.R1197Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1375395896, COSV100225375; called by muse, mutect2, varscan2
- ASCC3 | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1196291919; called by muse, mutect2
- ASCC3 | c.1758A>C p.E586D | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225661; called by muse, mutect2
- ASH1L | c.8227C>T p.R2743W (on ENST00000368346 / NM_001366177.2; = p.R2738W on NM_018489.3) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64213590; called by muse, mutect2, varscan2
- ASIC2 | c.1362T>G p.I454M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV56769289, COSV99859986; called by muse, mutect2, varscan2
- ASIC2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs754954730, COSV100726304; called by muse, mutect2, varscan2
- ASIC5 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV101611130; called by muse, mutect2, varscan2
- ASMTL | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs200707318, COSV101187745; called by muse, mutect2, varscan2
- ASNSD1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs753403228, COSV53623167, COSV99641395; called by muse, mutect2, varscan2
- ASPM | c.8227C>T p.R2743* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs774702591, CM1415104, COSV99659160; called by mutect2, varscan2
- ASPM | c.5009T>C p.V1670A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV99660219; called by muse, mutect2, varscan2
- ASPM | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 47/124 reads (38%) | catalogued as rs1215927812, COSV54132233, COSV99660220; called by muse, mutect2, varscan2
- ASPM | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV99660221; called by muse, mutect2, varscan2
- ASPRV1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as rs747852584, COSV57228976; called by muse, mutect2, varscan2
- ASTN1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs377210940, COSV56061502; called by muse, mutect2, varscan2
- ATAD5 | c.1775A>C p.K592T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100429925; called by muse, mutect2, varscan2
- ATF1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs763994606, COSV50394055; called by muse, mutect2, varscan2
- ATF7 | c.1306G>A p.A436T (on ENST00000548446 / NM_001366555.2; = p.A425T on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100129400; called by muse, mutect2, varscan2
- ATG2B | c.3790A>G p.T1264A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV99952031; called by muse, mutect2, varscan2
- ATG9A | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV100036924; called by muse, mutect2, varscan2
- ATM | c.7793G>A p.R2598Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140263969, CX030370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11B | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1218452517, COSV60026567; called by mutect2, varscan2
- ATP11B | c.2195T>G p.L732R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017737; called by muse, mutect2, varscan2
- ATP11C | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1033024084, COSV59559449, COSV59565145; called by muse, varscan2
- ATP11C | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 108/842 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV100557804; called by muse, varscan2
- ATP13A4 | c.3465G>T p.Q1155H | Missense Mutation (SNP) | VAF 42/501 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100710304; called by muse, mutect2
- ATP1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759097524, COSV100767806, COSV100768062; called by muse, mutect2, varscan2
- ATP1A3 | c.2607C>A p.F869L (on ENST00000545399 / NM_001256214.2; = p.F856L on NM_152296.5) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV57491436; called by muse, mutect2, varscan2
- ATP1A4 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as rs376262146, COSV63626819; called by muse, mutect2, varscan2
- ATP2B3 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs782080544, COSV54859713; called by muse, mutect2, varscan2
- ATP2B4 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100397440; called by muse, mutect2, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V1A | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99850088; called by muse, mutect2, varscan2
- ATP6V1B1 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV99314057; called by muse, mutect2, varscan2
- ATP7B | c.4189G>A p.A1397T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1220392640, COSV99666388; called by muse, mutect2, varscan2
- ATP8A2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99681663; called by muse, mutect2, varscan2
- ATP8A2 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99681664, COSV99682258; called by muse, mutect2
- ATP8B1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV52173638; called by muse, mutect2, varscan2
- ATP8B4 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52723464; called by muse, mutect2, varscan2
- ATP9B | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs140291894, COSV56956164; called by muse, varscan2
- ATR | c.3181G>T p.E1061* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | catalogued as COSV100638173, COSV63390295; called by muse, mutect2, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, varscan2
- ATRNL1 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as rs1554924686, COSV58114600; called by muse, mutect2
- ATXN1 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV99786218; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- ATXN7 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99894310; called by muse, mutect2, varscan2
- ATXN7L1 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.758); catalogued as COSV100596839; called by muse, mutect2, varscan2
- AURKC | c.773T>G p.F258C (on ENST00000302804 / NM_001015878.2; = p.F224C on NM_003160.3) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV100248829; called by muse, mutect2, varscan2
- AVPR2 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV100509499; called by muse, mutect2, varscan2
- B3GALT2 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100813590; called by muse, mutect2, varscan2
- B3GNT2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57345901; called by muse, mutect2, varscan2
- B3GNT7 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55007800; called by muse, mutect2
- B4GALNT2 | c.1500C>A p.F500L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55928499; called by muse, mutect2
- B4GALT3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 101/432 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100157712; called by muse, mutect2, varscan2
- BACH1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54518055; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BACH2 | c.1635C>A p.F545L | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57588636, COSV57607475; called by muse, mutect2, varscan2
- BAMBI | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.978); catalogued as COSV100977498; called by muse, mutect2, varscan2
- BANK1 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536273; called by muse, mutect2, varscan2
- BANK1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100536274; called by muse, mutect2, varscan2
- BANP | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1363604275, COSV53745462; called by muse, mutect2, varscan2
- BAZ1B | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100289720; called by muse, mutect2, varscan2
- BBOF1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs759690523, COSV101223845; called by muse, mutect2, varscan2
- BBS2 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs761068592, COSV55326240; called by muse, mutect2, varscan2
- BBS2 | c.720G>A p.S240= | Splice Region (SNP) | VAF 7/61 reads (11%) | catalogued as rs758715963, COSV99802370; called by muse, mutect2, varscan2
- BBS9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs541526329, COSV54169144; called by muse, mutect2, varscan2
- BCAS1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 151/796 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs145068978; called by muse, varscan2
- BCAS4 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as rs564853296, COSV52813195; called by muse, mutect2, varscan2
- BCL10 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV100997795, COSV65353814; called by muse, varscan2
- BCL9 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs782091140, COSV52342408; called by muse, mutect2, varscan2
- BDP1 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100703010; called by muse, mutect2
- BDP1 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1387255387, COSV62432953; called by muse, mutect2, varscan2
- BEND2 | c.2168A>C p.K723T | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV101191972, COSV66215845; called by muse, mutect2, varscan2
- BEND2 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 229/570 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs752043959, COSV66216785; called by muse, mutect2, varscan2
- BEND2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 172/768 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101191976; called by muse, mutect2, varscan2
- BEX1 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV101022484; called by muse, mutect2, varscan2
- BFSP1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746995142, COSV64899273; called by muse, mutect2, varscan2
- BHMT2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 76/286 reads (27%) | catalogued as COSV54872301, COSV54874260; called by muse, varscan2
- BICC1 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765378631, COSV99570484; called by muse, mutect2, varscan2
- BICD1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV55689476; called by muse, mutect2, varscan2
- BICD1 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.391); catalogued as COSV99862358; called by muse, mutect2, varscan2
- BIRC6 | c.3347A>C p.N1116T | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV101428237, COSV70206385; called by muse, mutect2, varscan2
- BIRC6 | c.5146G>A p.V1716I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV101428238; called by muse, mutect2, varscan2
- BIRC6 | c.5366G>T p.R1789I | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70196149; called by muse, mutect2, varscan2
- BIRC6 | c.8734G>A p.E2912K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs1448733090, COSV70201673, COSV70201836; called by muse, mutect2, varscan2
- BIRC6 | c.14548G>T p.E4850* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV70202505; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.521A>C p.K174T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1209063590, COSV99958721; called by muse, mutect2, varscan2
- BLZF1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV61393075; called by muse, varscan2
- BLZF1 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100250593; called by muse, varscan2
- BMP2K | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | catalogued as COSV100621693; called by muse, mutect2, varscan2
- BMP3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99261621, COSV99262050; called by muse, mutect2, varscan2
- BMP7 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs149261355; called by muse, mutect2, varscan2
- BMPR1B | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 122/578 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.315); catalogued as COSV99215788; called by muse, mutect2, varscan2
- BMPR1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215792; called by muse, mutect2, varscan2
- BMS1 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs753613781, COSV100996686; called by muse, mutect2, varscan2
- BNC1 | c.2346A>C p.E782D | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100597155; called by muse, mutect2, varscan2
- BNC2 | c.3222T>G p.F1074L | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101035930; called by muse, mutect2, varscan2
- BNC2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.096); catalogued as rs1287921241, COSV66147986; called by muse, mutect2, varscan2
- BNIP1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776652848, COSV51571239; called by muse, mutect2, varscan2
- BOC | c.3080C>A p.A1027D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV99848615; called by muse, mutect2
- BOD1L1 | c.1767G>T p.K589N | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99239238; called by muse, mutect2
- BOD1L1 | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99239240; called by muse, mutect2, varscan2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, mutect2, varscan2
- BPI | c.848G>A p.R283H (on ENST00000262865; = p.R279H on NM_001725.3) | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs183269384; called by muse, mutect2, varscan2
- BPIFA1 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100845638; called by muse, varscan2
- BPIFC | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs369618463, COSV100300744, COSV100301024; called by muse, mutect2, varscan2
- BPNT1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs760682156, COSV100435646; called by muse, mutect2
- BPTF | c.3952A>C p.K1318Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100074802; called by muse, mutect2
- BRAP | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 61/361 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV100554112; called by muse, mutect2, varscan2
- BRCC3 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.42); catalogued as COSV100341581; called by muse, varscan2
- BRD1 | c.2987G>T p.R996I (on ENST00000216267 / NM_001349940.1; = p.R1127I on NM_001304808.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99349686; called by mutect2, varscan2
- BRD2 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs140400525, COSV66372360; called by muse, mutect2
- BRD2 | c.2271G>A p.A757= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as rs199954603, COSV100875660; called by muse, mutect2, varscan2
- BRDT | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as COSV100746342, COSV62867386; called by muse, mutect2, varscan2
- BRDT | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV62867987; called by muse, mutect2, varscan2
- BRIP1 | c.3213A>T p.E1071D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.693); catalogued as COSV99369980; called by muse, mutect2
- BRIP1 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 165/734 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369983; called by muse, mutect2, varscan2
- BRMS1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs768620232, COSV100240228, COSV100240244; called by muse, mutect2, varscan2
- BRPF3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160592236, COSV60207201; called by muse, mutect2, varscan2
- BRWD3 | c.5302T>G p.F1768V | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV64746189; called by muse, mutect2
- BRWD3 | c.5236C>T p.R1746* | Nonsense Mutation (SNP) | VAF 87/278 reads (31%) | catalogued as rs868344048, COSV100955976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.4988G>T p.R1663I | Missense Mutation (SNP) | VAF 197/516 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV64745986; called by muse, mutect2, varscan2
- BRWD3 | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs867108306, COSV100956282, COSV64747596; called by muse, mutect2, varscan2
- BRWD3 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 61/358 reads (17%) | catalogued as rs866592729, COSV64746272; called by muse, mutect2, varscan2
- BRWD3 | c.1682A>C p.Y561S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100955980, COSV64749133; called by muse, mutect2, varscan2
- BTAF1 | c.3190A>C p.N1064H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99795261; called by muse, mutect2, varscan2
- BTBD11 | c.2915T>G p.I972S (on ENST00000280758 / NM_001018072.2; = p.I509S on NM_001017523.2) | Missense Mutation (SNP) | VAF 138/729 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99775562; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, mutect2, varscan2
- BTK | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.952); catalogued as rs1555977836, COSV100437565; called by muse, mutect2, varscan2
- BTN2A2 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100760372; called by muse, mutect2, varscan2
- BTN2A2 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100760374; called by muse, mutect2
- BUB1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.27); catalogued as COSV100241217; called by muse, mutect2, varscan2
- BUB1B | c.2988C>A p.F996L | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99806853; called by muse, mutect2, varscan2
- BVES | c.741A>C p.E247D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV100114897; called by muse, mutect2, varscan2
- C10orf88 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64403572; called by muse, mutect2, varscan2
- C12orf4 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 162/2280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99712707; called by muse, mutect2
- C12orf4 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 38/203 reads (19%) | catalogued as COSV99712710; called by muse, mutect2, varscan2
- C12orf54 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100011594; called by muse, mutect2, varscan2
- C12orf56 | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100399348; called by muse, mutect2, varscan2
- C16orf71 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV100172912; called by muse, mutect2, varscan2
- C16orf87 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99587510; called by muse, mutect2, varscan2
- C17orf75 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56752769, COSV99858633; called by muse, mutect2, varscan2
- C17orf97 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs966859189, COSV100789313; called by muse, mutect2, varscan2
- C1GALT1C1L | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370033463; called by muse, mutect2, varscan2
- C1QC | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65889277; called by muse, mutect2, varscan2
- C1QL2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55606522, COSV55607948; called by muse, mutect2, varscan2
- C1R | c.402C>A p.F134L (on ENST00000536053 / NM_001354346.2; = p.F120L on NM_001733.7) | Missense Mutation (SNP) | VAF 121/587 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56924379, COSV99864661; called by muse, mutect2, varscan2
- C1orf100 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as COSV100353341; called by muse, mutect2
- C2CD3 | c.2367T>G p.N789K | Missense Mutation (SNP) | VAF 174/797 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV100486561; called by muse, varscan2
- C2CD6 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs370301019; called by muse, mutect2, varscan2
- C2orf16 | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100820772; called by muse, mutect2, varscan2
- C2orf16 | c.3127C>A p.L1043I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs1254880586, COSV62678979; called by muse, mutect2, varscan2
- C3 | c.4678G>A p.E1560K | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.111); catalogued as rs750498103, COSV99836547; called by muse, mutect2, varscan2
- C4orf50 | c.800T>C p.V267A (on ENST00000324058; = p.V1499A on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV60689788; called by muse, mutect2, varscan2
- C5AR2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as rs758673260, COSV57255706; called by muse, mutect2, varscan2
- C6 | c.2463G>T p.E821D | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as COSV99667003; called by muse, mutect2, varscan2
- C6orf58 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs766884453, COSV100314861; called by muse, mutect2, varscan2
- C6orf62 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100965865; called by muse, mutect2
- C6orf89 | c.106G>T p.E36* (on ENST00000373685; = p.E43* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100769721, COSV100769751; called by muse, varscan2
- C6orf89 | c.958G>A p.D320N (on ENST00000373685; = p.D327N on NM_152734.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs79686273; called by muse, mutect2, varscan2
- C7 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1561262611; called by muse, mutect2
- C7orf26 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760205435, COSV100732892; called by muse, mutect2
- C8orf34 | c.1289T>G p.I430R | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV100298108; called by muse, mutect2, varscan2
- C9 | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 151/631 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54675814; called by muse, mutect2, varscan2
- C9orf131 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100398083, COSV56611074; called by muse, mutect2, varscan2
- CABS1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.215); catalogued as rs573726918, COSV56733628; called by muse, mutect2, varscan2
- CABYR | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV100510035; called by muse, mutect2, varscan2
- CACHD1 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99261328; called by muse, mutect2, varscan2
- CACNA1A | c.4876C>A p.L1626M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV100802265; called by muse, mutect2, varscan2
- CACNA1B | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs747544100, COSV53137448; called by muse, mutect2, varscan2
- CACNA1C | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100218328; called by muse, mutect2, varscan2
- CACNA1E | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100702318; called by muse, mutect2, varscan2
- CACNA1F | c.5131C>T p.P1711S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782006249, COSV100544722, COSV59905550; called by muse, mutect2, varscan2
- CACNA1F | c.3367A>C p.I1123L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.23); catalogued as COSV100544724; called by muse, mutect2, varscan2
- CACNA1F | c.1981C>A p.L661I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100544725; called by muse, mutect2, varscan2
- CACNA1S | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs768968718, COSV100754957; called by muse, varscan2
- CACNG2 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100268786; called by muse, mutect2, varscan2
- CACNG5 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 59/511 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.076); catalogued as COSV99400553; called by muse, mutect2, varscan2
- CADM3 | c.997A>G p.I333V (on ENST00000368125 / NM_001127173.3; = p.I367V on NM_021189.5) | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100929902; called by muse, mutect2, varscan2
- CADPS2 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100462556; called by muse, mutect2, varscan2
- CALCRL | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101130935; called by muse, mutect2, varscan2
- CALD1 | c.1978A>C p.S660R (on ENST00000361675 / NM_033138.4; = p.S405R on NM_004342.7) | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100724196; called by muse, mutect2, varscan2
- CALD1 | c.2311G>T p.D771Y (on ENST00000361675 / NM_033138.4; = p.D516Y on NM_004342.7) | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724199; called by muse, mutect2, varscan2
- CALHM6 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100889440; called by muse, mutect2, varscan2
- CAMKMT | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs759924384, COSV101034655; called by muse, mutect2, varscan2
- CAMKV | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV99615455; called by muse, mutect2, varscan2
- CAMSAP1 | c.885A>C p.E295D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV100409804; called by muse, mutect2
- CAND2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384678711, COSV55987665; called by muse, mutect2, varscan2
- CAND2 | c.931G>A p.D311N (on ENST00000456430 / NM_001162499.2; = p.D218N on NM_012298.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs756369567, COSV99929029; called by muse, mutect2, varscan2
- CAPN2 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99688853; called by muse, mutect2, varscan2
- CAPN6 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100136851; called by muse, mutect2, varscan2
- CAPN6 | c.700T>C p.S234P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100136853; called by muse, mutect2, varscan2
- CAPNS1 | c.759A>C p.Q253H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV99497064; called by muse, mutect2, varscan2
- CAPRIN2 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1402077640, COSV99195484; called by muse, mutect2, varscan2
- CAPZA2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100753932, COSV63266023; called by muse, mutect2
- CARD8 | c.1605G>T p.Q535H (on ENST00000651546 / NM_001184900.3; = p.Q485H on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100751100; called by muse, mutect2, varscan2
- CARMIL1 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61525502; called by muse, mutect2
- CASD1 | c.1106A>C p.Q369P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.266); catalogued as rs1253941819, COSV99802573; called by muse, mutect2, varscan2
- CASK | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs771368987, COSV100587107; called by muse, mutect2
- CASP5 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99507529; called by muse, mutect2, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by muse, mutect2, varscan2
- CASS4 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs866071361, COSV100824666; called by muse, mutect2, varscan2
- CAT | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752948472, COSV99573064, COSV99573216; called by muse, mutect2, varscan2
- CATSPER1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150298490; called by muse, mutect2, varscan2
- CAV2 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV56063830, COSV99760773; called by muse, mutect2, varscan2
- CBFB | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs761036715, COSV51996734, COSV51999572, COSV52001985; called by muse, mutect2, varscan2
- CBLB | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV51420650, COSV51426325; called by muse, mutect2, varscan2
- CBLIF | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 190/765 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV99950931; called by muse, mutect2, varscan2
- CBLL2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as rs908529189, COSV100081687, COSV60368760; called by muse, mutect2
- CCAR1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308578865, COSV56274352; called by muse, varscan2
- CCAR1 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV56270744, COSV99770764; called by muse, varscan2
- CCDC102B | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100103369; called by muse, mutect2, varscan2
- CCDC110 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV56872519; called by muse, mutect2, varscan2
- CCDC112 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 100/392 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101100434; called by muse, mutect2, varscan2
- CCDC114 | c.1130-1G>T p.X377_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100196698; called by muse, mutect2, varscan2
- CCDC148 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99320298; called by muse, mutect2, varscan2
- CCDC150 | c.2262T>C p.I754= | Splice Region (SNP) | VAF 23/74 reads (31%) | catalogued as rs1211355009, COSV99776864; called by muse, mutect2, varscan2
- CCDC158 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as COSV101187230; called by muse, mutect2, varscan2
- CCDC158 | c.1794A>C p.E598D | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101187231; called by muse, mutect2, varscan2
- CCDC158 | c.1368G>T p.K456N | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs949970281, COSV101187232, COSV66355493; called by muse, mutect2
- CCDC160 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100892109; called by muse, varscan2
- CCDC160 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100892111; called by muse, mutect2, varscan2
- CCDC170 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 42/192 reads (22%) | catalogued as rs370430081; called by muse, mutect2, varscan2
- CCDC170 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV53342826, COSV99498385; called by muse, mutect2, varscan2
- CCDC171 | c.440G>T p.R147I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV99900548; called by muse, mutect2, varscan2
- CCDC171 | c.1077-1G>T p.X359_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as rs766740699, COSV99900550; called by muse, mutect2, varscan2
- CCDC174 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100358567; called by muse, mutect2, varscan2
- CCDC174 | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100358568; called by muse, mutect2, varscan2
- CCDC178 | c.1263T>G p.F421L | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as COSV100284727; called by muse, mutect2, varscan2
- CCDC18 | c.1842G>T p.K614N (on ENST00000343253 / NM_001306076.1; = p.K615N on NM_206886.4) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV58143177; called by muse, mutect2, varscan2
- CCDC186 | c.1455A>C p.E485D | Missense Mutation (SNP) | VAF 142/530 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as COSV100991106; called by muse, mutect2, varscan2
- CCDC34 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1273782378, COSV58725275; called by muse, mutect2
- CCDC39 | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 100/430 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV56490396, COSV99868585; called by muse, mutect2, varscan2
- CCDC54 | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99660190; called by muse, mutect2
- CCDC58 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52246989; called by muse, mutect2, varscan2
- CCDC59 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 113/612 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99810655; called by muse, mutect2, varscan2
- CCDC73 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV58795993; called by muse, mutect2, varscan2
- CCDC81 | c.1766G>A p.R589K (on ENST00000445632 / NM_001156474.2; = p.R499K on NM_021827.4) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99564274; called by muse, mutect2, varscan2
- CCDC88A | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV55061573; called by muse, mutect2, varscan2
- CCER1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100727021; called by muse, mutect2, varscan2
- CCL13 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV99861718; called by muse, mutect2, varscan2
- CCL18 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs540060026; called by muse, mutect2, varscan2
- CCL23 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs202213083; called by muse, mutect2, varscan2
- CCN1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV71704396; called by muse, mutect2, varscan2
- CCN1 | c.841A>C p.K281Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs754796443; called by mutect2, varscan2
- CCNB1IP1 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100738558; called by muse, mutect2, varscan2
- CCNB1IP1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV100738559; called by muse, mutect2, varscan2
- CCNB3 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99328939; called by muse, mutect2, varscan2
- CCNE1 | c.819A>C p.Q273H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV99388370; called by muse, mutect2, varscan2
- CCNQ | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99367953; called by muse, mutect2, varscan2
- CCNT1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV56064925; called by muse, mutect2
- CCR1 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV99946696; called by muse, mutect2, varscan2
- CCSER1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100388549; called by muse, mutect2, varscan2
- CCSER2 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779512549, COSV99825874; called by muse, mutect2, varscan2
- CCT4 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771250995, COSV101075184; called by muse, mutect2, varscan2
- CCT8L2 | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63462153, COSV63462489, COSV63462823; called by muse, varscan2
- CD101 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs199631117; called by muse, mutect2, varscan2
- CD109 | c.4102A>C p.N1368H | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99753467; called by muse, mutect2, varscan2
- CD109 | c.4235G>A p.G1412D | Missense Mutation (SNP) | VAF 162/685 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99753470; called by muse, mutect2, varscan2
- CD163 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs868312071, COSV100775818; called by muse, varscan2
- CD163 | c.1858C>A p.L620I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV100775819, COSV104418153; called by muse, varscan2
- CD180 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99842223; called by muse, mutect2, varscan2
- CD22 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99323153; called by muse, mutect2, varscan2
- CD22 | c.2190C>A p.F730L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV99323154; called by muse, mutect2
- CD274 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs897885359, COSV101055992; called by muse, mutect2, varscan2
- CD300LD | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100032415; called by muse, mutect2
- CD4 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163756; called by muse, mutect2, varscan2
- CD40LG | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1350282799, COSV65699086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD40LG | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776239740, COSV101033486; called by muse, varscan2
- CD63 | c.468A>C p.K156N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99141767; called by muse, mutect2, varscan2
- CD8B | c.699G>T p.Q233H (on ENST00000331469 / NM_172213.4; = p.Q203H on NM_172102.4) | Missense Mutation (SNP) | VAF 151/488 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV100514488; called by muse, mutect2, varscan2
- CDC14A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs371468460, COSV100325925; called by muse, mutect2, varscan2
- CDC14B | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99685637; called by muse, mutect2, varscan2
- CDC20B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1008892536, COSV57054773; called by muse, mutect2, varscan2
- CDC37L1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101116522; called by muse, mutect2, varscan2
- CDC5L | c.2336A>G p.E779G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV101015010; called by muse, mutect2, varscan2
- CDH11 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV51756404, COSV99218170; called by muse, mutect2
- CDH11 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV51758880; called by muse, varscan2
- CDH12 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.606); catalogued as COSV101202417, COSV66397283; called by muse, mutect2, varscan2
- CDH18 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1434063547, COSV56927210, COSV99931214; called by muse, varscan2
- CDH2 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52285382, COSV99296721; called by muse, mutect2, varscan2
- CDH22 | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV100952833; called by muse, mutect2, varscan2
- CDH6 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV99417950; called by muse, mutect2, varscan2
- CDH7 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542242; called by muse, varscan2
- CDH9 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV50257873; called by muse, varscan2
- CDH9 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99144122; called by muse, mutect2, varscan2
- CDHR3 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 108/529 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV100488277; called by muse, mutect2, varscan2
- CDK12 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000304; called by muse, mutect2
- CDK13 | c.4525G>A p.G1509R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV51703259, COSV99475467; called by muse, mutect2, varscan2
- CDK15 | c.632G>A p.G211D (on ENST00000652192 / NM_001366386.2; = p.G160D on NM_139158.2) | Missense Mutation (SNP) | VAF 93/511 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53639161, COSV99643096; called by muse, mutect2, varscan2
- CDK17 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99702692; called by muse, mutect2, varscan2
- CDK2 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99906719; called by muse, mutect2
- CDK20 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV100308066; called by muse, mutect2, varscan2
- CDK6 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as rs761377867, COSV56008615; called by muse, mutect2, varscan2
- CDKL1 | c.868A>C p.N290H | Missense Mutation (SNP) | VAF 203/654 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV99367419; called by muse, mutect2, varscan2
- CDKL2 | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV100276895; called by muse, mutect2
- CDKL2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs755711267, COSV56733569; called by muse, mutect2, varscan2
- CDKL3 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99527826; called by muse, mutect2, varscan2
- CDKL3 | c.684T>A p.F228L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99527831; called by muse, mutect2
- CDKL4 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 297/1210 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV101115262; called by muse, mutect2, varscan2
- CDKL5 | c.1835C>A p.S612Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV101184286; called by muse, mutect2, varscan2
- CDON | c.2586T>G p.F862L | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99701261; called by muse, mutect2, varscan2
- CDON | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as COSV99701263; called by muse, mutect2, varscan2
- CDRT1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs761413180; called by muse, varscan2
- CEACAM18 | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV101140335; called by muse, mutect2, varscan2
- CEACAM4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs201492288, COSV55731164; called by muse, mutect2, varscan2
- CEACAM8 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV99747375, COSV99747595; called by muse, varscan2
- CEBPE | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs200138272; called by muse, mutect2, varscan2
- CELSR2 | c.2705G>A p.R902H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1446038037, COSV54775168; called by muse, mutect2
- CELSR3 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs561081554, COSV99373388; called by muse, mutect2, varscan2
- CEMIP2 | c.1807C>A p.H603N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100987356; called by muse, mutect2, varscan2
- CENATAC | c.684G>A p.Q228= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as rs781960489, COSV57724159; called by muse, varscan2
- CENPJ | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV99693048; called by muse, mutect2, varscan2
- CENPJ | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761545596, COSV67883223; called by mutect2, varscan2
- CENPN | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528102999, COSV55141477; called by muse, mutect2, varscan2
- CENPU | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV55656322, COSV99859897; called by muse, mutect2, varscan2
- CENPW | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as rs745347945, COSV64176920; called by muse, mutect2
- CEP112 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs377414265; called by muse, mutect2, varscan2
- CEP120 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 55/571 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60268820; called by muse, mutect2
- CEP128 | c.2387T>C p.I796T | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV99824499; called by muse, mutect2, varscan2
- CEP135 | c.1300A>C p.K434Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.242); catalogued as COSV99954390; called by muse, mutect2, varscan2
- CEP192 | c.2718T>G p.S906R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV100381119; called by muse, mutect2, varscan2
- CEP290 | c.7159G>T p.D2387Y | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100468587; called by muse, mutect2, varscan2
- CEP290 | c.5428A>C p.N1810H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV100468588; called by muse, mutect2, varscan2
- CEP290 | c.3133A>C p.K1045Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100468591; called by muse, mutect2, varscan2
- CEP290 | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100468596; called by muse, mutect2, varscan2
- CEP350 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 59/274 reads (22%) | catalogued as COSV62486180; called by muse, mutect2, varscan2
- CEP350 | c.8921C>T p.A2974V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1472246820, COSV62605206; called by muse, varscan2
- CEP43 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs868230727, COSV100835591; called by muse, mutect2, varscan2
- CEP68 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53124180; called by muse, mutect2, varscan2
- CEP70 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs763266142, COSV99389125; called by muse, mutect2, varscan2
- CEP78 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV99450351; called by muse, mutect2
- CEP78 | c.1123G>T p.E375* (on ENST00000424347 / NM_001349840.2; = p.E376* on NM_032171.3) | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as rs1451630903, COSV99450358, COSV99450909; called by muse, mutect2, varscan2
- CEP78 | c.1575G>T p.E525D (on ENST00000424347 / NM_001349840.2; = p.E526D on NM_032171.3) | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52846492; called by muse, mutect2, varscan2
- CEP83 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.178); catalogued as rs587777487, CM145883, COSV60409884; called by muse, varscan2
- CEP83 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 187/890 reads (21%) | catalogued as COSV100352834, COSV60406636; called by muse, mutect2, varscan2
- CEP95 | c.1064T>C p.F355S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV73609326; called by muse, mutect2, varscan2
- CEP95 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs567605055, COSV73609379; called by muse, varscan2
- CES5A | c.810+2T>C p.X270_splice | Splice Site (SNP) | VAF 27/121 reads (22%) | catalogued as rs1226293603, COSV99307481; called by muse, mutect2, varscan2
- CETP | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs138898516, COSV99570117; called by muse, mutect2, varscan2
- CFAP206 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as rs377042908; called by muse, mutect2, varscan2
- CFAP20DC | c.1409C>T p.S470F (on ENST00000482387 / NM_001351530.2; = p.S345F on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99918615; called by muse, mutect2, varscan2
- CFAP251 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 23/224 reads (10%) | catalogued as rs1018120311, COSV56609735; called by muse, mutect2, varscan2
- CFAP251 | c.3406C>A p.L1136I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56610809; called by muse, mutect2, varscan2
- CFAP47 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.604); catalogued as COSV99934928; called by muse, varscan2
- CFAP53 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 232/929 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs751078877, COSV68353065; called by muse, mutect2, varscan2
- CFAP54 | c.5312A>C p.N1771T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100733147; called by muse, mutect2, varscan2
- CFAP69 | c.883A>C p.N295H | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100290053; called by muse, mutect2
- CFAP70 | c.2630C>A p.S877* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as rs551423264, COSV100160542; called by mutect2, varscan2
- CFAP94 | c.940G>T p.E314* (on ENST00000320267 / NM_001352064.2; = p.E320* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 121/786 reads (15%) | catalogued as COSV100209264; called by muse, varscan2
- CFAP94 | c.909A>C p.Q303H (on ENST00000320267 / NM_001352064.2; = p.Q309H on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/832 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV100209267; called by muse, varscan2
- CFH | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100809468, COSV66411741; called by muse, mutect2, varscan2
- CFTR | c.4324A>C p.S1442R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.797); catalogued as COSV99135780; called by muse, mutect2, varscan2
- CGGBP1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as rs1350839978, COSV58851580; called by muse, mutect2, varscan2
- CH25H | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV100897348; called by muse, mutect2, varscan2
- CHAD | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV51972104; called by muse, mutect2, varscan2
- CHD2 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100560678; called by muse, mutect2, varscan2
- CHD4 | c.3974G>T p.R1325I (on ENST00000357008 / NM_001363606.2; = p.R1338I on NM_001273.5) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58895972, COSV58909317; called by muse, mutect2, varscan2
- CHD5 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs751854770, COSV99311991; called by muse, mutect2, varscan2
- CHD6 | c.3462C>A p.F1154L | Missense Mutation (SNP) | VAF 178/565 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100498185, COSV58560672; called by muse, mutect2, varscan2
- CHD7 | c.6992A>G p.K2331R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs747050794, COSV101418219; called by muse, mutect2, varscan2
- CHD8 | c.4895C>T p.S1632L (on ENST00000646647 / NM_001170629.2; = p.S1353L on NM_020920.4) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100783814; called by muse, mutect2, varscan2
- CHD9 | c.4918G>T p.E1640* | Nonsense Mutation (SNP) | VAF 90/932 reads (10%) | catalogued as rs767991192, COSV99529107; called by muse, mutect2
- CHFR | c.700C>T p.L234F (on ENST00000432561 / NM_001161345.1; = p.L193F on NM_018223.2) | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs35206714; called by muse, mutect2, varscan2
- CHGB | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 14/290 reads (5%) | catalogued as COSV100972956; called by muse, mutect2
- CHIC1 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 138/390 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV100998235; called by muse, mutect2, varscan2
- CHIT1 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs746089762, COSV55147829; called by muse, mutect2, varscan2
- CHL1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1286726671, COSV99851044; called by muse, mutect2
- CHL1 | c.2299A>C p.N767H (on ENST00000397491 / NM_001253387.1; = p.N783H on NM_006614.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99851046; called by muse, mutect2, varscan2
- CHMP3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs747374601, COSV55685994, COSV99806656; called by muse, mutect2, varscan2
- CHRM2 | c.623A>C p.H208P | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100281208; called by muse, mutect2
- CHRNA2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs372418511, COSV99532200; called by muse, mutect2, varscan2
- CHRNA9 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375832887; called by muse, mutect2, varscan2
- CHRNB3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1162798881, COSV51497466; called by muse, mutect2, varscan2
- CHST13 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV60042282; called by mutect2, varscan2
- CHST15 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs1228198265, COSV60564145; called by muse, mutect2, varscan2
- CHST15 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.732); catalogued as rs750731230, COSV100655103; called by mutect2, varscan2
- CHST7 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.411); catalogued as COSV99332916; called by muse, mutect2, varscan2
- CHST9 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV99410072; called by muse, mutect2, varscan2
- CHSY1 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs776069033, COSV54252183; called by muse, mutect2, varscan2
- CIB3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs1181779868; called by muse, mutect2, varscan2
- CIBAR2 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV101608272; called by muse, mutect2, varscan2
- CIITA | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1200008888, COSV60857594; called by muse, mutect2
- CILP | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs772689886, COSV99973319; called by muse, mutect2, varscan2
- CILP2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs188436574, COSV99364638; called by muse, mutect2, varscan2
- CIR1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs768225837, COSV59595336; called by muse, mutect2, varscan2
- CIT | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs754496604, COSV99949437; called by muse, mutect2, varscan2
- CKAP4 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376479872; called by muse, mutect2, varscan2
- CLASP1 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs368425278; called by muse, mutect2, varscan2
- CLASRP | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs779406462, COSV99673787; called by muse, mutect2, varscan2
- CLC | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 29/256 reads (11%) | catalogued as COSV99695605; called by muse, mutect2, varscan2
- CLCA1 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as rs200279591, COSV99322290; called by muse, mutect2, varscan2
- CLCA4 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as rs1014964478, COSV99760285, COSV99760457; called by muse, mutect2, varscan2
- CLCA4 | c.1908G>T p.Q636H | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV55368392, COSV99760463; called by muse, mutect2
- CLCN4 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as rs1273441566, COSV101073787; called by muse, mutect2, varscan2
- CLDN7 | c.373A>C p.I125L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as COSV100598245, COSV63040437; called by muse, mutect2, varscan2
- CLEC12B | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 258/672 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100138968; called by muse, mutect2, varscan2
- CLEC16A | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101277946; called by muse, mutect2, varscan2
- CLEC16A | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749052302, COSV68497981; called by muse, mutect2, varscan2
- CLEC4C | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.759); catalogued as COSV63582424; called by muse, mutect2, varscan2
- CLEC5A | c.53T>G p.V18G | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV101407764; called by muse, varscan2
- CLEC6A | c.486-1G>T p.X162_splice | Splice Site (SNP) | VAF 22/92 reads (24%) | catalogued as COSV101165647; called by muse, mutect2, varscan2
- CLIP1 | c.1427G>A p.R476H (on ENST00000620786 / NM_001247997.1; = p.R465H on NM_002956.2) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV56798440; called by muse, mutect2, varscan2
- CLIP4 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 87/356 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100191862; called by muse, mutect2, varscan2
- CLIP4 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1001775106, COSV100191865; called by muse, mutect2, varscan2
4,181 further variants in this file (3,138 protein-altering or splice-affecting, 943 silent, 100 other) are not listed here.
